HCMI case HCM-EXPT-1034-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/87d5b9f8-a744-4419-87bf-b68a5e55cf2f

Demographics
Sex at birth: female; Year of birth: 1940.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 78.7 years (28,733 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1034-C50-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1034-C50-06A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 78; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1034-C50-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 93; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 7; Percent lymphocyte infiltration: 13; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
